HCMI case HCM-SANG-1316-C18 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/82ce9f95-f322-4867-8abb-266b5b8289d0

Demographics
Sex at birth: male; Days to birth: -30,863 days (84.5 years before the index date).

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.7; Tissue or organ of origin: Colon, NOS; Classification of tumor: primary; Tumor grade: G2; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Liver; Uicc clinical stage: Stage IVA; Uicc pathologic m: M1; Uicc pathologic n: N0; Uicc pathologic stage: Stage IVA; Uicc pathologic t: T0; Uicc staging system edition: 7th.
   Recorded as not given: neoadjuvant treatment (type not reported).
2. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C78.7; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Liver; Classification of tumor: metastasis.
   Pathology details: Lymphatic invasion present: No; Perineural invasion present: No; Vascular invasion present: No.

Follow-up (1 entry)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to progression: 0 days.

Molecular and laboratory tests
- MLH1 (IHC): Positive.
- MSH2 (IHC): Positive.
- MSH6 (IHC): Positive.
- PMS2 (IHC): Positive.
- Test: Negative; Mismatch repair mutation: Yes.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples)
- Sample HCM-SANG-1316-C18-06A-01D-A80T-32: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: Frozen.
- Sample HCM-SANG-1316-C18-10A-01D-A80T-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
- Samples HCM-SANG-1316-C18-85A-01D-A80T-32, HCM-SANG-1316-C18-85A-01R-A80W-32 (2 with the same recorded description): Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
